Somatic mutation profile of tumor specimen TARGET-40-NAAIBU-01A (aliquot TARGET-40-NAAIBU-01A-01D) from TARGET case TARGET-40-NAAIBU, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 7.2 years (2,628 days).
Specimen TARGET-40-NAAIBU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb48715c-0d6c-48f7-98ff-af1acddd03cc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAIBU-10B (Blood Derived Normal), aliquot TARGET-40-NAAIBU-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd87126e-9f81-44e2-9679-64d1f2ba2ced

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL1 | c.2593G>T p.A865S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV61523543; called by muse, mutect2
- CNTNAP5 | c.1931G>C p.G644A | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV70482037; called by muse, mutect2, varscan2
- PTPRB | c.704T>C p.M235T | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs776085240; called by muse, mutect2, varscan2
- RB1 | c.219_220dup p.A74Efs*4 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as COSV57297594; called by mutect2, varscan2
- CACNA1B | c.3385T>C p.S1129P | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC168 | c.13582T>C p.S4528P | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- CLUH | c.2738A>G p.E913G (on ENST00000435359; = p.E952G on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CORO2A | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- NUP210 | c.4761C>A p.N1587K | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- RIPOR1 | c.287A>G p.H96R (on ENST00000379312 / NM_001193522.2; = p.H92R on NM_024519.4) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CLSTN1 | c.1536A>G p.E512= (on ENST00000377298 / NM_001009566.3; = p.E502= on NM_014944.4) | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- GET4 | c.648C>T p.F216= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
